Gene-level copy-number profile of tumor specimen TARGET-40-PASFCV-01A from TARGET case TARGET-40-PASFCV, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 10.5 years (3,849 days).
Specimen TARGET-40-PASFCV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.77227754-851e-5155-a2e5-debff82f4839.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PASFCV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 362 have no estimate.
https://portal.gdc.cancer.gov/files/a4802e7c-6c8d-4e49-bce2-94ae76ff3046

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 528; copy number 1: 1; copy number 2: 1,240; copy number 3: 11,786; copy number 4: 17,714; copy number 5: 9,255; copy number 6: 12,811; copy number 7: 2,575; copy number 8: 720; copy number 9: 2,620; copy number 10: 420; copy number 11: 434; copy number 12: 60; copy number 13: 9; copy number 15: 5; copy number 29: 82; copy number 33: 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–5): AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr6:150,934,968–150,939,328, 2 genes: ARL4AP5, RNU6-302P.
- chr12:9,480,608–9,576,275, 2 genes (within-gene range 0–6): AC092821.1, AC092821.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,631 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–203,904,013, 1,585 genes, copy number 9 (broad region; genes not listed).
- chr2:214,241,676–215,349,773, 14 genes, copy number 10: AC068051.1, RPL5P8, VWC2L, VWC2L-IT1, ENSAP3, BARD1, SNHG31, SNORA70I, RPL10P6, ABCA12, AC072062.1, AC092844.1, LINC02862, ATIC.
- chr4:30,718,805–41,824,119, 138 genes, copy number 9 (broad region; genes not listed).
- chr4:44,533,615–45,051,652, 10 genes, copy number 10: AC093852.1, YIPF7, GUF1, GNPDA2, AC096586.2, AC096586.1, AC093755.1, PRDX4P1, AC108467.2, AC108467.1.
- chr4:52,872,982–53,366,066, 1 gene, copy number 9 (within-gene range 7–9): SCFD2.
- chr4:53,265,461–63,143,881, 135 genes, copy number 9 (broad region; genes not listed).
- chr4:68,509,441–68,628,899, 5 genes, copy number 15: UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3.
- chr6:37,630,679–37,699,306, 1 gene, copy number 11: MDGA1.
- chr6:49,273,600–49,636,839, 9 genes, copy number 13: FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG.
- chr6:51,385,282–52,190,638, 11 genes, copy number 9: AL158050.2, AL158050.1, AL365219.1, AL445529.1, AL355997.1, PKHD1, RN7SL580P, MIR206, LINCMD1, MIR133B, IL17A.
- chr6:52,939,726–53,219,424, 16 genes, copy number 12: GSTA9P, AL121969.1, GSTA4, 7SK, RN7SK, CILK1, AL031178.1, FBXO9, AL031178.2, RN7SL244P, AL512347.1, GCM1, RNU6-464P, SOD1P1, AL512378.1, RNU1-136P.
- chr6:53,336,943–54,945,099, 32 genes, copy number 12: RPS16P5, AL034374.1, RPL31P28, RPL31P33, RPA3P2, AL591034.1, RN7SKP256, NANOGP3, GCLC, AL033397.2, AL033397.1, LINC01564, KLHL31, AL590652.1, LRRC1, AL033384.2, MLIP, AL033384.1, MLIP-AS1, MLIP-IT1, ERHP2, AL359380.1, TINAG, TINAG-AS1, CLNS1AP1, RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1.
- chr6:55,327,469–56,954,649, 12 genes, copy number 12 (within-gene range 6–12): GFRAL, HMGCLL1, AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26.
- chr6:61,240,898–62,611,327, 8 genes, copy number 10: AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2.
- chr7:70,972–22,357,154, 344 genes, copy number 9–10 (broad region; genes not listed).
- chr7:23,298,739–29,742,594, 148 genes, copy number 10 (broad region; genes not listed).
- chr7:48,708,327–52,503,434, 43 genes, copy number 9–10: LINC02838, AC004899.1, AC004899.2, GDI2P1, CDC14C, AC091730.1, DDX43P2, AC092448.1, AC093775.1, VWC2, ZPBP, GNL2P1, AC034148.1, SPATA48, AC020743.1, AC020743.2, AC020743.3, IKZF1, AC124014.1, RNU6-1091P, FIGNL1, DDC, DDC-AS1, GRB10, AC005153.1, AC004920.1, AC009296.1, AC004830.2, AC004830.1, COBL, RPL7L1P2, CICP17, AC012441.2, AC012441.1, AC005999.2, ROBO2P1, AC005999.1, RN7SL292P, AC006478.1, AC006478.2, AC079763.1, AC006320.1, AC006459.1.
- chr12:66,767–2,889,524, 71 genes, copy number 10–11 (broad region; genes not listed).
- chr12:2,885,819–2,886,329, 1 gene, copy number 11: AC005911.1.
- chr14:18,333,726–24,335,093, 458 genes, copy number 11–33 (within-gene range 6–33) (broad region; genes not listed).
- chr17:142,789–1,684,867, 50 genes, copy number 9 (within-gene range 3–9): DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB, AC015853.2, VPS53, AC015853.3, AC015853.1, AC027455.1, RPS4XP17, TLCD3A, GEMIN4, DBIL5P, GLOD4, AC087392.3, MRM3, AC087392.4, AC087392.5, NXN, AC087392.2, AC087392.1, AC036164.1, TIMM22, ABR, MIR3183, Metazoa_SRP, AC016292.2, AC016292.1, AC144836.1, BHLHA9, TRARG1, YWHAE, AC032044.2, CRK, AC032044.1, MYO1C, INPP5K, PITPNA-AS1, PITPNA, SLC43A2, RN7SL105P, SCARF1, RILP, PRPF8.
- chr17:7,717,354–16,990,177, 269 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr17:17,504,005–22,706,703, 270 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
